Gene-level copy-number profile of tumor specimen HCM-BROD-0955-C15-06A from HCMI case HCM-BROD-0955-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,191 days).
Specimen HCM-BROD-0955-C15-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 396650ed-f206-4356-aa71-afa5cf605360.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0955-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/82c491a7-8f03-423c-8709-bc9abb6246f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 3,145; copy number 2: 25,800; copy number 3: 18,717; copy number 4: 7,699; copy number 5: 2,022; copy number 6: 335; copy number 7: 192; copy number 8: 359; copy number 9: 13; copy number 10: 17; copy number 13: 1; copy number 16: 14; copy number 21: 5; copy number 35: 4; copy number 58: 31.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr5:58,582,221–58,859,394, 3 genes (within-gene range 0–2): RAB3C, AC016642.1, RPL5P15.
- chr5:60,021,249–60,033,020, 1 gene (within-gene range 0–2): AC034234.1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr18:51,028,394–51,085,045, 1 gene (within-gene range 0–2): SMAD4.
- chr19:4,043,303–4,066,899, 2 genes: ZBTB7A, AC016586.1.
- chr19:7,888,505–7,903,542, 2 genes: LRRC8E, AC010336.1.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–4): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:44,107,373–44,210,114, 3 genes (within-gene range 0–2): PWP2, GATD3A, LINC01678.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,993 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–165,582,155, 887 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:73,571,550–73,714,527, 2 genes, copy number 5: RASSF6, UMLILO.
- chr5:58,198–14,699,850, 253 genes, copy number 5 (broad region; genes not listed).
- chr5:14,872,332–45,895,970, 422 genes, copy number 5 (broad region; genes not listed).
- chr6:27,780,619–27,831,560, 9 genes, copy number 6: RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11, H4C12.
- chr7:95,297,676–96,110,322, 12 genes, copy number 5–6: PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1.
- chr7:97,200,708–105,115,019, 256 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:114,922,359–117,323,152, 52 genes, copy number 16–58: MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr7:117,363,222–117,440,780, 2 genes, copy number 58: ASZ1, ANKRD49P4.
- chr9:72,051,376–73,080,442, 17 genes, copy number 5: C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P.
- chr11:10,507,894–10,611,689, 5 genes, copy number 6 (within-gene range 4–6): MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1.
- chr11:33,787,054–34,102,610, 8 genes, copy number 5: AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1.
- chr11:35,618,460–35,661,339, 2 genes, copy number 5: FJX1, AL138812.1.
- chr12:24,566,964–27,824,382, 82 genes, copy number 5 (broad region; genes not listed).
- chr13:27,819,376–44,809,630, 273 genes, copy number 6–10 (broad region; genes not listed).
- chr13:45,120,510–45,284,893, 1 gene, copy number 8 (within-gene range 2–8): GTF2F2.
- chr13:45,192,853–53,939,960, 190 genes, copy number 8 (broad region; genes not listed).
- chr14:20,223,710–21,643,578, 99 genes, copy number 5–7 (broad region; genes not listed).
- chr16:25,419,812–28,323,849, 43 genes, copy number 5–9: LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1, AC002331.1, LINC02195, AC009035.1, C16orf82, AC092725.1, EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1, KATNIP, AC002551.1, AC016597.1, AC016597.2, Y_RNA, GSG1L, RNU6-159P, RNU6-1241P, XPO6, TPRKBP2, AC136611.1, RNY1P10, GAPDHP35, AC138904.3, SBK1, AC138904.1.
- chr16:28,341,437–28,539,008, 14 genes, copy number 5: AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7, CLN3, APOBR, IL27, NUPR1.
- chr16:28,548,331–28,554,140, 2 genes, copy number 5 (within-gene range 4–5): AC020765.1, AC020765.2.
- chr16:29,995,715–31,150,083, 115 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:30,378,927–31,095,450, 46 genes, copy number 5 (within-gene range 4–5): CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1, TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733.
- chr17:39,461,486–40,598,585, 57 genes, copy number 5: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2.
- chr17:70,778,604–71,298,218, 4 genes, copy number 6: AC007423.1, AC005181.1, CASC17, RNU7-155P.
- chr19:14,514,769–14,612,035, 7 genes, copy number 6: DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P.
- chr19:15,159,038–17,287,646, 118 genes, copy number 6 (broad region; genes not listed).
- chr20:31,514,410–31,607,240, 9 genes, copy number 5: HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193.
- chr21:8,701,461–8,701,562, 1 gene, copy number 13: CR381572.1.
- chr21:10,640,028–13,067,033, 5 genes, copy number 5: AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 801. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
